CCDI case PBCJMP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/83acebb9-5083-471c-b483-a7cd79bc9637

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Aggressive fibromatosis: ICD-O-3 morphology code: 8821/1; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 1.1 years (409 days).

Biospecimens (3 samples)
- Sample 0DV144: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DV14H: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV152: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
